Gene-level copy-number profile of tumor specimen TCGA-XV-A9W5-01A from TCGA case TCGA-XV-A9W5, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 51.3 years (18,739 days).
Specimen TCGA-XV-A9W5-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SKCM.9060b5e3-a53d-4c24-9837-0aab3a5fcf7c.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-XV-A9W5-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/5af79372-2c29-45ee-a3a6-2bcb7d16e3d7

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 45; copy number 1: 7,948; copy number 2: 44,524; copy number 3: 6,196; copy number 4: 924; copy number 5: 112; copy number 6: 16; copy number 7: 54.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-XV-A9W5-01A-11D-A38F-01): tumor purity 0.72, ploidy 2.02, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 45 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:21,186,694–22,128,103, 45 genes: IFNA4, IFNWP9, IFNA7, IFNA10, IFNWP18, IFNA16, IFNA17, IFNWP5, IFNA14, IFNA22P, IFNA5, IFNA20P, KLHL9, IFNA6, IFNA13, IFNA2, AL353732.1, IFNA11P, IFNA12P, IFNA8, AL353732.2, IFNWP2, IFNA1, MIR31HG, IFNWP19, IFNE, MIR31, SNORD39, H3P30, KHSRPP1, RN7SL151P, MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 182 genes in 13 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:38,253,380–38,318,861, 11 genes, copy number 7: TRGJ2, TRGJP2, TRGC1, TRGJ1, TRGJP, TRGJP1, TRGV11, TRGVB, TRGV10, AC006033.1, TRGV9.
- chr9:22,646,200–22,824,213, 1 gene, copy number 6 (within-gene range 3–6): LINC01239.
- chr9:22,747,700–22,748,234, 1 gene, copy number 6: CLIC4P1.
- chr9:29,824,742–29,826,711, 1 gene, copy number 5: ME2P1.
- chr9:38,360,427–38,424,454, 3 genes, copy number 5: AL135785.1, ALDH1B1, IGFBPL1.
- chr9:72,871,130–73,751,077, 9 genes, copy number 5: LINC01474, ALDH1A1, CYP1D1P, ANXA1, DPP3P2, AL451127.2, AL451127.1, AL512594.1, RNA5SP286.
- chr9:74,935,176–75,028,423, 4 genes, copy number 5 (within-gene range 2–5): AL158825.1, C9orf40, CARNMT1-AS1, CARNMT1.
- chr11:69,414,307–71,252,577, 43 genes, copy number 7 (within-gene range 1–7): AP005233.1, AP000439.2, AP000439.1, AP000439.3, LINC02747, LINC01488, CCND1, LTO1, FGF19, DNAJB6P5, FGF4, FGF3, AP007216.1, AP007216.2, AP003555.2, AP003555.1, LINC02753, LINC02584, RNU6-1175P, ANO1, AP000879.2, ANO1-AS1, FADD, AP000879.1, PPFIA1, H2AZP4, AP002336.2, MIR548K, AP002336.1, AP002336.3, AP000487.2, AP000487.1, CTTN, SHANK2, AP001271.1, AP001271.2, SHANK2-AS1, SHANK2-AS2, Y_RNA, AP000590.1, SHANK2-AS3, MIR3664, AP003783.1.
- chr11:74,012,718–74,498,533, 19 genes, copy number 5–6 (within-gene range 1–6): C2CD3, AP002392.1, PPME1, RNA5SP343, AP000577.2, P4HA3, AP000577.1, P4HA3-AS1, PGM2L1, HNRNPA1P40, AP001372.1, AP001085.1, MIR548AL, KCNE3, AP001372.3, CYCSP27, AP001372.4, LIPT2, AP001372.2.
- chr11:80,321,620–81,431,520, 7 genes, copy number 5: AP006295.1, RNU6-544P, ARL6IP1P3, LINC02720, AP003398.1, AP003398.2, AP003464.1.
- chr16:3,365,099–3,479,550, 1 gene, copy number 5 (within-gene range 4–5): AC025283.2.
- chr16:3,382,081–5,235,822, 80 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr16:6,037,210–6,092,954, 2 genes, copy number 5: AC009135.2, AC009135.1.

Autosomal genes at a single copy (total copy number 1): 5,568. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
